Somatic mutation profile of tumor specimen TCGA-HT-A61A-01A (aliquot TCGA-HT-A61A-01A-11D-A29Q-08) from TCGA case TCGA-HT-A61A, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 21.0 years (7,664 days).
Specimen TCGA-HT-A61A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08f6ae87-f9bc-47c4-802d-16de86ef78f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A61A-10A (Blood Derived Normal), aliquot TCGA-HT-A61A-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/717ffda2-56ff-47d7-81be-53d7c40010a1

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH6A1 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761850051, COSV63246139; called by muse, mutect2, varscan2
- BRCA2 | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs80358439, CM151861, COSV66451879; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2
- EPN2 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59060753; called by muse, mutect2
- GALNT14 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200913085, COSV100205210, COSV61104127; called by muse, mutect2, varscan2
- GHR | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.227); catalogued as COSV50109592; called by muse, mutect2, varscan2
- LPAR2 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382938307, COSV52556474; called by muse, mutect2
- POLR3A | c.1345A>G p.I449V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as rs756675053, COSV64930795; called by muse, mutect2, varscan2
